Somatic mutation profile of tumor specimen C3N-01200-04 (aliquot CPT0075150012) from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06f11f31-62ec-4fd9-80f5-ab14a797f64a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01200-71 (Blood Derived Normal), aliquot CPT0075240001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa088ae8-2840-435b-813b-835272af15ff

The open-access MAF lists 92 somatic variants for this specimen: 50 protein-altering or splice-affecting, 21 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 21, Intron 13, Frame Shift Del 5, 3'UTR 5, Frame Shift Ins 3, In Frame Del 3, Splice Region 1, RNA 1, 5'UTR 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.758dup p.T254Dfs*30 | Frame Shift Ins (INS) | VAF 75/276 reads (27%) | catalogued as rs1553645591; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP1A3 | c.1778C>G p.S593C (on ENST00000545399 / NM_001256214.2; = p.S580C on NM_152296.5) | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57487252; called by muse, mutect2, varscan2
- BTBD3 | c.1207A>C p.K403Q | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs759996580; called by muse, mutect2, varscan2
- EEA1 | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1172307888; called by muse, mutect2, varscan2
- GLRA3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864626; called by muse, mutect2, varscan2
- ITGB2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs1053155608, COSV100186060; called by muse, mutect2, varscan2
- KIR3DL1 | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 28/199 reads (14%) | catalogued as rs758317602; called by muse, mutect2, varscan2
- KRTAP22-2 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 29/126 reads (23%) | PolyPhen possibly damaging (0.617); catalogued as COSV66962843; called by muse, mutect2, varscan2
- MBP | c.562C>T p.R188W (on ENST00000355994 / NM_001025101.2; = p.R55W on NM_002385.3) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766571087; called by muse, mutect2, varscan2
- MICAL2 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56320093; called by muse, mutect2, varscan2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- SLC19A1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs776173955, COSV60756989; called by muse, mutect2, varscan2
- USP12 | c.500C>G p.P167R | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV99997488; called by muse, mutect2
- AC097518.1 | n.166C>T | Splice Region (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- CASD1 | c.2264T>C p.I755T | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASK | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CBX3 | c.448T>A p.L150M | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, varscan2
- CSMD3 | c.9249T>A p.D3083E (on ENST00000297405 / NM_001363185.1; = p.D2914E on NM_052900.3) | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF7 | c.276_284del p.D93_L95del | In Frame Del (DEL) | VAF 28/153 reads (18%) | called by mutect2, pindel
- DNAH11 | c.11714del p.G3905Vfs*12 | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel, varscan2
- DNAH5 | c.7391del p.G2464Afs*2 | Frame Shift Del (DEL) | VAF 30/134 reads (22%) | called by mutect2, pindel, varscan2
- ELL2 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FOXB2 | c.599dup p.Q201Afs*73 | Frame Shift Ins (INS) | VAF 28/112 reads (25%) | called by mutect2, pindel, varscan2
- GRIPAP1 | c.380_406del p.A127_G135del | In Frame Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- HAS3 | c.1227T>G p.I409M | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IGDCC4 | c.1801A>C p.I601L | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNG2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KIFAP3 | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LAMC3 | c.2048T>G p.F683C | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCE3A | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 80/412 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MTMR3 | c.2322del p.L775Sfs*24 | Frame Shift Del (DEL) | VAF 44/279 reads (16%) | called by mutect2, pindel, varscan2
- NFATC2 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- OR9Q2 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PKD1 | c.6186G>T p.Q2062H | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PLA2G3 | c.1091T>G p.F364C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- POLE | c.1399T>A p.Y467N | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- REM1 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SALL3 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SCAMP3 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SNX5 | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- SPANXN5 | c.154_156del p.L52del | In Frame Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, pindel, varscan2
- SPART | c.783del p.L262* | Frame Shift Del (DEL) | VAF 27/150 reads (18%) | called by mutect2, pindel, varscan2
- SPATS2 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- VHL | c.610_614del p.E204Hfs*50 | Frame Shift Del (DEL) | VAF 73/300 reads (24%) | called by mutect2, pindel, varscan2
- VPS35 | c.1499_1500dup p.E501Lfs*9 | Frame Shift Ins (INS) | VAF 33/228 reads (14%) | called by mutect2, pindel, varscan2
- WDR6 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF256 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF470 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF831 | c.1790C>A p.A597D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ZSCAN5A | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADCY6 | c.2322C>A p.A774= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs1362941438; called by muse, mutect2, varscan2
- AHNAK | c.6627A>T p.V2209= | Silent (SNP) | VAF 88/427 reads (21%) | called by muse, mutect2, varscan2
- AL162231.1 | c.163C>T p.L55= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- CDK11B | c.1002G>A p.E334= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as rs1279885928; called by mutect2, varscan2
- CENPE | c.2013A>G p.L671= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99477122; called by muse, mutect2, varscan2
- CORT | c.15C>T p.P5= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs375806455; called by muse, mutect2
- FMN2 | c.1119C>T p.D373= | Silent (SNP) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- HDX | c.18A>G p.V6= | Silent (SNP) | VAF 16/76 reads (21%) | called by muse, varscan2
- IFIH1 | c.2532G>A p.E844= | Silent (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
- KCNG2 | c.1254G>A p.Q418= | Silent (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- MFSD6 | c.1326C>T p.L442= | Silent (SNP) | VAF 68/164 reads (41%) | called by muse, mutect2, varscan2
- MS4A4E | c.126G>A p.R42= | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as rs267603050; called by muse, mutect2, varscan2
- NOTCH3 | c.1335G>A p.T445= | Silent (SNP) | VAF 32/214 reads (15%) | catalogued as rs568403807, COSV54650413; called by muse, mutect2, varscan2
- NPY5R | c.1254T>C p.C418= | Silent (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- OR13C5 | c.531C>T p.F177= | Silent (SNP) | VAF 28/217 reads (13%) | catalogued as COSV66165252; called by muse, varscan2
- PAK4 | c.939C>T p.D313= | Silent (SNP) | VAF 72/309 reads (23%) | catalogued as rs369018322; called by muse, mutect2
- PLEKHA4 | c.441G>T p.A147= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as rs1404611123; called by muse, mutect2, varscan2
- PLXDC2 | c.1395C>A p.L465= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as COSV65904134; called by muse, mutect2, varscan2
- TTN | c.84165A>C p.T28055= (on ENST00000591111; = p.T20631= on NM_003319.4) | Silent (SNP) | VAF 15/109 reads (14%) | called by muse, varscan2
- VEZF1 | c.348C>A p.I116= | Silent (SNP) | VAF 47/200 reads (24%) | called by muse, mutect2, varscan2
- ZNF227 | c.2082G>A p.G694= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- AC106741.1 | c.*39G>T | 3'UTR (SNP) | VAF 40/146 reads (27%) | catalogued as rs1339151046; called by muse, mutect2, varscan2
- CD320 | c.*205G>C | 3'UTR (SNP) | VAF 56/214 reads (26%) | called by muse, mutect2, varscan2
- FAM193B | c.1076+18A>C | Intron (SNP) | VAF 53/256 reads (21%) | called by muse, mutect2, varscan2
- FGFR4 | c.1057+165_1057+166del | Intron (DEL) | VAF 72/394 reads (18%) | called by pindel, varscan2
- FOXP2 | c.*2787_*2788del | 3'UTR (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- GYS2 | c.1890+47A>G | Intron (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- HBD | c.-29+230G>C | Intron (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- LINC02694 | n.107A>C | RNA (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- MT1G | c.97+82_97+84del | Intron (DEL) | VAF 41/222 reads (18%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.210-29G>T | Intron (SNP) | VAF 49/246 reads (20%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158773 C>T | 5'Flank (SNP) | VAF 26/103 reads (25%) | catalogued as rs772284609; called by muse, mutect2, varscan2
- RPL4 | c.-24G>A | 5'UTR (SNP) | VAF 18/122 reads (15%) | catalogued as rs371027636; called by muse, mutect2, varscan2
- RTN4R | c.23-414C>A | Intron (SNP) | VAF 21/81 reads (26%) | called by muse, varscan2
- SLC11A2 | c.*1609T>C | 3'UTR (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- SLC2A1 | c.868-50del | Intron (DEL) | VAF 34/213 reads (16%) | called by mutect2, pindel, varscan2
- TMEM134 | c.329+28C>T | Intron (SNP) | VAF 41/192 reads (21%) | catalogued as rs201248558; called by muse, mutect2, varscan2
- TMEM258 | c.3+19G>T | Intron (SNP) | VAF 51/214 reads (24%) | called by muse, mutect2, varscan2
- UNC5A | c.293-2546C>A | Intron (SNP) | VAF 8/129 reads (6%) | catalogued as COSV56165821; called by muse, mutect2
- USP32P3 | n.3271+886C>A | Intron (SNP) | VAF 60/370 reads (16%) | called by muse, mutect2, varscan2
- VAPB | c.*4774A>G | 3'UTR (SNP) | VAF 56/288 reads (19%) | catalogued as COSV55666798; called by muse, mutect2, varscan2
- ZEB1 | c.58+43636G>T | Intron (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
